Gene-level copy-number profile of tumor specimen TCGA-76-6662-01A from TCGA case TCGA-76-6662, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,511 days).
Specimen TCGA-76-6662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ace571a4-d5a4-4fac-a922-eff114d5a3cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-76-6662-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8821da10-3a40-4c53-be23-dfbec20645da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,284; copy number 2: 49,411; copy number 3: 2; copy number 4: 3,028; copy number 8: 1; copy number 26: 3; copy number 27: 1; copy number 28: 60; copy number 29: 12; copy number 30: 1; copy number 31: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-76-6662-01A-11D-1842-01): tumor purity 0.59, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 95 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–205,457,091, 60 genes, copy number 28: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B.
- chr1:234,811,052–235,328,219, 14 genes, copy number 31 (within-gene range 2–31): AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753.
- chr18:67,481,791–68,114,878, 12 genes, copy number 29: AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.
- chr18:70,205,774–70,208,781, 1 gene, copy number 8: AC021701.1.
- chr18:72,742,314–72,868,146, 1 gene, copy number 31 (within-gene range 3–31): NETO1.
- chr18:72,853,321–72,881,399, 2 genes, copy number 31: MIR548AV, AC091138.1.
- chr18:75,642,494–75,656,016, 1 gene, copy number 30: AC090338.1.
- chr18:76,008,118–76,015,861, 1 gene, copy number 27: AC090457.1.
- chr18:76,357,682–76,495,242, 1 gene, copy number 26 (within-gene range 2–26): ZNF516.
- chr18:76,491,629–76,498,088, 2 genes, copy number 26: AC018413.1, ZNF516-DT.

Autosomal genes at a single copy (total copy number 1): 4,897. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
